Somatic mutation profile of tumor specimen 0DX7FQ from CCDI case PBCPXC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.1 years (3,703 days).
Specimen 0DX7FQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1014b012-43b7-422a-a509-fef3d1adbcdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7ES (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e18d7d9-ed5a-4022-be52-ae3b6c3d327a

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Ins 3, Silent 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR174 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs750403868, COSV52132211; called by muse, mutect2, varscan2
- SCYL2 | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 86/523 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.04); catalogued as rs758295522; called by muse, mutect2, varscan2
- AGBL3 | c.741dup p.E248Rfs*20 | Frame Shift Ins (INS) | VAF 121/319 reads (38%) | called by mutect2, varscan2
- GPS2 | c.469dup p.Q157Pfs*49 | Frame Shift Ins (INS) | VAF 150/197 reads (76%) | called by mutect2, varscan2
- GRIN1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KREMEN2 | c.1211dup p.A405Gfs*34 (on ENST00000303746 / NM_172229.3; = p.R378Pfs*60 on NM_024507.4) | Frame Shift Ins (INS) | VAF 46/90 reads (51%) | called by mutect2, varscan2
- LRRC24 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 120/271 reads (44%) | called by muse, mutect2, varscan2
- YARS1 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 157/445 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GPR148 | c.960C>T p.Y320= | Silent (SNP) | VAF 121/289 reads (42%) | catalogued as rs564497650; called by muse, mutect2, varscan2
- NDRG1 | c.856-82G>T | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
